Somatic mutation profile of tumor specimen MP2PRT-PAVUPL-TMP1-A (aliquot MP2PRT-PAVUPL-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVUPL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,724 days).
Specimen MP2PRT-PAVUPL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5832718-29e5-429f-a161-ac377668e8bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUPL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUPL-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bdd37a1-8f3e-4128-b55c-6661502fb2a7

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Nonsense Mutation 3, In Frame Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FSIP2 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs965981113; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1481C>G p.S494* | Nonsense Mutation (SNP) | VAF 58/326 reads (18%) | called by muse, mutect2, varscan2
- C11orf65 | c.128G>C p.R43T | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.714); called by muse, varscan2
- CADPS | c.551A>T p.Y184F | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD7 | c.6628G>T p.E2210* | Nonsense Mutation (SNP) | VAF 79/422 reads (19%) | called by muse, mutect2, varscan2
- DSCAM | c.2021A>T p.E674V | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- FAP | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- HS6ST2 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 75/487 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR6B3 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- PKD1L1 | c.6848_6850dup p.A2283_L2284insP | In Frame Ins (INS) | VAF 40/296 reads (14%) | called by mutect2, pindel, varscan2
- WSCD2 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ANOS1 | c.1656G>A p.E552= | Silent (SNP) | VAF 56/304 reads (18%) | catalogued as COSV99391354; called by muse, mutect2, varscan2
- CHRNA7 | c.1179C>T p.D393= | Silent (SNP) | VAF 151/1045 reads (14%) | catalogued as rs752171678; called by muse, mutect2, varscan2
- CTPS2 | c.96C>T p.L32= | Silent (SNP) | VAF 77/357 reads (22%) | called by muse, mutect2, varscan2
- LCMT1 | c.165G>C p.V55= | Silent (SNP) | VAF 53/245 reads (22%) | called by muse, mutect2, varscan2
- PARP12 | c.1701C>T p.S567= | Silent (SNP) | VAF 82/496 reads (17%) | catalogued as rs145495111; called by muse, mutect2, varscan2
- SLC7A14 | c.2154G>A p.E718= | Silent (SNP) | VAF 89/346 reads (26%) | called by muse, mutect2, varscan2
- CCPG1 | c.*3265G>C | 3'UTR (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- THSD4 | c.1153-113112C>G | Intron (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2, varscan2
